FM case AD5780 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acinar Cell Neoplasms; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/932f3ed6-53c2-46de-ae90-10ae6bb811d1

Male, 56.8 years: Acinar adenocarcinoma (ICD-O-3 8550/3) of the prostate gland; primary biopsied or resected from the prostate gland. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
